Somatic mutation profile of tumor specimen ALCH-B05X-TTP1-A (aliquot ALCH-B05X-TTP1-A-1-0-D-A680-36) from ALCHEMIST case ALCH-B05X, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.9 years (22,227 days).
Specimen ALCH-B05X-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e99d869-3b9e-485a-ae70-2da7a14e2efa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B05X-NB1-A (Blood Derived Normal), aliquot ALCH-B05X-NB1-A-1-0-D-A680-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f0d5567-4bf1-4125-831e-9ddb9455219a

The open-access MAF lists 195 somatic variants for this specimen: 123 protein-altering or splice-affecting, 42 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 42, Intron 18, Nonsense Mutation 8, RNA 6, Frame Shift Del 4, Splice Site 4, 3'UTR 3, 5'Flank 3, Splice Region 2, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 80/415 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADGRB3 | c.3895C>A p.P1299T | Missense Mutation (SNP) | VAF 86/305 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs779451522; called by muse, mutect2, varscan2
- AMER3 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs776197488, COSV100365953; called by muse, mutect2, varscan2
- ANXA11 | c.1087G>T p.E363* | Nonsense Mutation (SNP) | VAF 32/139 reads (23%) | catalogued as rs1280746389; called by muse, mutect2, varscan2
- AURKC | c.425G>T p.R142L (on ENST00000302804 / NM_001015878.2; = p.R108L on NM_003160.3) | Missense Mutation (SNP) | VAF 60/570 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV57137565; called by muse, mutect2, varscan2
- BIRC6 | c.2608C>T p.R870* | Nonsense Mutation (SNP) | VAF 74/314 reads (24%) | catalogued as rs752993442; called by muse, mutect2, varscan2
- CCNT1 | c.497-2A>T p.X166_splice | Splice Site (SNP) | VAF 28/140 reads (20%) | catalogued as rs770254128; called by mutect2, varscan2
- CD200R1L | c.230G>T p.C77F | Missense Mutation (SNP) | VAF 93/570 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV101236582; called by muse, mutect2, varscan2
- CEP131 | c.239C>T p.T80M | Missense Mutation (SNP) | VAF 59/312 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs528966168, COSV53954587; called by muse, mutect2, varscan2
- CHST3 | c.797G>T p.R266L | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.361); catalogued as rs768853633, COSV100910517; called by muse, mutect2, varscan2
- ELOVL6 | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 147/545 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV56430729; called by muse, mutect2, varscan2
- FLG | c.1594C>A p.H532N | Missense Mutation (SNP) | VAF 222/777 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs758635510, COSV64236350; called by muse, mutect2, varscan2
- GDF1 | c.304G>A p.V102M | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs763476348; called by muse, mutect2, varscan2
- IGKV1D-8 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 100/597 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as rs374084493; called by muse, mutect2, varscan2
- IGSF9B | c.1477G>A p.V493M | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.671); catalogued as rs1468741985, COSV58069416; called by muse, mutect2, varscan2
- KCNK9 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 120/463 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.014); catalogued as rs372850659, COSV57278227; called by muse, mutect2, varscan2
- KLHDC4 | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.063); catalogued as rs753693075; called by muse, mutect2, varscan2
- MAGEB4 | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 27/273 reads (10%) | catalogued as COSV100974865; called by muse, mutect2
- MASP1 | c.1510C>A p.R504S | Missense Mutation (SNP) | VAF 130/657 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV61826645; called by muse, mutect2, varscan2
- MEX3D | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 49/207 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777933894, COSV66312088, COSV66312412; called by muse, mutect2, varscan2
- MKI67 | c.5120C>T p.P1707L | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1330238891; called by muse, mutect2, varscan2
- MR1 | c.479C>T p.T160I | Missense Mutation (SNP) | VAF 130/809 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs756059027; called by muse, mutect2, varscan2
- MSL3 | c.529C>T p.P177S (on ENST00000312196 / NM_078629.4; = p.P11S on NM_006800.4) | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100384745, COSV56496519; called by muse, mutect2, varscan2
- MUC17 | c.6686C>A p.T2229N | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.134); catalogued as COSV60286392; called by muse, mutect2, varscan2
- NFASC | c.2689C>T p.R897C (on ENST00000339876 / NM_001378329.1; = p.R1000C on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 274/856 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs1309632528, COSV58367643; called by muse, mutect2, varscan2
- NTM | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 142/641 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66183570; called by muse, mutect2, varscan2
- PCDHB12 | c.1345C>A p.P449T | Missense Mutation (SNP) | VAF 144/663 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1171178715; called by muse, mutect2, varscan2
- PRDM9 | c.1193C>A p.S398* | Nonsense Mutation (SNP) | VAF 143/679 reads (21%) | catalogued as COSV57010800; called by muse, mutect2, varscan2
- PRKDC | c.9580G>A p.E3194K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.029); catalogued as rs769618690, COSV58059035, COSV58060127; called by muse, mutect2, varscan2
- PSG11 | c.787G>T p.A263S | Missense Mutation (SNP) | VAF 32/286 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as rs527275238, COSV60453877; called by muse, mutect2, varscan2
- PZP | c.1449G>T p.M483I | Missense Mutation (SNP) | VAF 60/228 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99062421; called by muse, mutect2, varscan2
- SCFD2 | c.163C>T p.H55Y | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1560467873; called by muse, mutect2, varscan2
- SLC12A8 | c.766G>T p.D256Y | Missense Mutation (SNP) | VAF 50/278 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58869548; called by muse, mutect2, varscan2
- SLC9A4 | c.1219A>G p.I407V | Missense Mutation (SNP) | VAF 95/351 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as rs1367156241; called by muse, mutect2, varscan2
- SRRM3 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 27/317 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782707622; called by muse, mutect2
- STYXL2 | c.1338del p.H446Qfs*6 | Frame Shift Del (DEL) | VAF 22/167 reads (13%) | catalogued as COSV54801882, COSV54804509; called by mutect2, pindel, varscan2
- SYNDIG1 | c.277C>T p.L93F | Missense Mutation (SNP) | VAF 84/442 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs763667811; called by muse, mutect2, varscan2
- TMEM132C | c.2473C>G p.R825G | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.963); catalogued as rs919803681; called by muse, mutect2, varscan2
- VWA5B1 | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 54/425 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374632705, COSV57055123; called by muse, mutect2, varscan2
- ZFHX4 | c.2099G>A p.R700H | Missense Mutation (SNP) | VAF 76/383 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781379151, COSV51466756, COSV99268536; called by muse, mutect2, varscan2
- ABCC11 | c.547T>A p.L183M | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); called by muse, varscan2
- ACE | c.3035C>A p.P1012H | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACYP2 | c.94A>G p.R32G | Missense Mutation (SNP) | VAF 60/317 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- AGA | c.745G>T p.D249Y | Missense Mutation (SNP) | VAF 141/558 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- AGAP3 | c.593C>T p.T198M (on ENST00000622464; = p.T234M on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATIC | c.82G>T p.G28C | Missense Mutation (SNP) | VAF 208/1024 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BTN1A1 | c.509A>T p.Y170F | Missense Mutation (SNP) | VAF 109/490 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CAMSAP3 | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- CASTOR2 | c.514C>G p.Q172E | Missense Mutation (SNP) | VAF 97/488 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH11 | c.2035G>T p.A679S | Missense Mutation (SNP) | VAF 63/389 reads (16%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- CDH24 | c.565del p.V189Cfs*38 | Frame Shift Del (DEL) | VAF 50/296 reads (17%) | called by mutect2, pindel, varscan2
- CDH3 | c.1111G>T p.G371C | Missense Mutation (SNP) | VAF 120/589 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP20 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 62/247 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLIP4 | c.716A>C p.D239A | Missense Mutation (SNP) | VAF 100/446 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); called by muse, mutect2
- COL11A2 | c.1972-1G>T p.X658_splice (on ENST00000341947 / NM_080680.3; = p.X551_splice on NM_080679.2) | Splice Site (SNP) | VAF 65/252 reads (26%) | called by muse, mutect2, varscan2
- CSMD1 | c.7038G>C p.Q2346H (on ENST00000520002; = p.Q2345H on NM_033225.6) | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CTDP1 | c.2666G>T p.R889L | Missense Mutation (SNP) | VAF 53/236 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- DNM1 | c.1196+5G>C | Splice Region (SNP) | VAF 62/182 reads (34%) | called by muse, mutect2, varscan2
- DPP6 | c.358G>T p.A120S (on ENST00000377770 / NM_001364500.2; = p.A58S on NM_001936.5) | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DPP6 | c.358+1G>T p.X120_splice (on ENST00000377770 / NM_001364500.2; = p.X58_splice on NM_001936.5) | Splice Site (SNP) | VAF 24/141 reads (17%) | called by muse, mutect2, varscan2
- DSEL | c.3103A>T p.R1035W | Missense Mutation (SNP) | VAF 59/232 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- EPHA8 | c.2584G>T p.G862C | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FLG | c.1593C>A p.H531Q | Missense Mutation (SNP) | VAF 225/780 reads (29%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FMO4 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 50/326 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GOLGA8S | c.188G>C p.G63A | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.029); called by mutect2, varscan2
- GRXCR2 | c.730C>A p.Q244K | Missense Mutation (SNP) | VAF 76/397 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- HHLA1 | c.1240G>A p.G414S | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- HIPK1 | c.889C>T p.Q297* | Nonsense Mutation (SNP) | VAF 36/245 reads (15%) | called by muse, mutect2, varscan2
- HS3ST1 | c.848A>G p.N283S | Missense Mutation (SNP) | VAF 79/376 reads (21%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGSF1 | c.14G>T p.R5I | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- IL4R | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 73/300 reads (24%) | called by muse, varscan2
- ITGAX | c.406C>A p.Q136K | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KAT6A | c.4337G>C p.C1446S | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- KCNH8 | c.2043G>T p.V681= | Splice Region (SNP) | VAF 40/238 reads (17%) | called by muse, varscan2
- L1TD1 | c.1777A>G p.K593E | Missense Mutation (SNP) | VAF 69/269 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- LAMB3 | c.3277G>T p.G1093C | Missense Mutation (SNP) | VAF 184/1315 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- LONRF3 | c.421_435del p.T141_A145del | In Frame Del (DEL) | VAF 54/297 reads (18%) | called by pindel, varscan2
- LRFN5 | c.516C>A p.S172R | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- MADD | c.4806A>T p.K1602N | Missense Mutation (SNP) | VAF 98/440 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MOV10L1 | c.2788G>T p.A930S | Missense Mutation (SNP) | VAF 53/270 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- MRGPRE | c.320A>G p.Y107C | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MUC16 | c.34799C>A p.S11600* | Nonsense Mutation (SNP) | VAF 73/302 reads (24%) | called by muse, mutect2, varscan2
- MUC16 | c.3932G>T p.G1311V | Missense Mutation (SNP) | VAF 35/241 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MUC2 | c.3507G>T p.K1169N | Missense Mutation (SNP) | VAF 77/273 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- NDUFA5 | c.173T>C p.M58T | Missense Mutation (SNP) | VAF 118/513 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OCA2 | c.1805A>G p.K602R | Missense Mutation (SNP) | VAF 69/638 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- OR14A2 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 163/497 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR14A2 | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 166/494 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- OR5H14 | c.451G>C p.G151R | Missense Mutation (SNP) | VAF 79/656 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); called by muse, varscan2
- OR7E24 | c.569T>C p.V190A | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- OR8H1 | c.782C>G p.P261R | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PCDH10 | c.254G>A p.C85Y | Missense Mutation (SNP) | VAF 52/236 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDCD11 | c.5024A>T p.E1675V | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PDCD11 | c.5025G>T p.E1675D | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- PELI1 | c.187C>A p.P63T | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- PHACTR3 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 70/427 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PKHD1L1 | c.4810C>T p.P1604S | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); called by muse, varscan2
- PNLIPRP3 | c.786T>A p.F262L | Missense Mutation (SNP) | VAF 81/351 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- PNMA5 | c.776T>C p.V259A | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- PNPLA6 | c.2746A>T p.T916S (on ENST00000414982 / NM_001166111.2; = p.T868S on NM_006702.5) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, varscan2
- PRRC2A | c.3512G>A p.G1171D | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- RFX8 | c.91C>A p.P31T | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RYR2 | c.3658G>T p.D1220Y | Missense Mutation (SNP) | VAF 212/698 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- SH2D4B | c.1235G>T p.G412V (on ENST00000646907; = p.R337S on NM_207372.2) | Missense Mutation (SNP) | VAF 72/382 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- SLC17A3 | c.1219G>C p.D407H | Missense Mutation (SNP) | VAF 96/462 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- SMC4 | c.1824dup p.S609Ifs*18 | Frame Shift Ins (INS) | VAF 59/309 reads (19%) | called by mutect2, varscan2
- SNTG1 | c.1202A>G p.Y401C | Missense Mutation (SNP) | VAF 47/229 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- STAB2 | c.2834G>T p.R945L | Missense Mutation (SNP) | VAF 46/315 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- STK11 | c.141del p.K48Sfs*3 | Frame Shift Del (DEL) | VAF 133/465 reads (29%) | called by pindel, varscan2
- STRA8 | c.911T>A p.V304E (on ENST00000275764; = p.V282E on NM_182489.2) | Missense Mutation (SNP) | VAF 74/271 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SVEP1 | c.6343G>T p.G2115C | Missense Mutation (SNP) | VAF 108/340 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TG | c.8188+1G>T p.X2730_splice | Splice Site (SNP) | VAF 107/489 reads (22%) | called by muse, mutect2, varscan2
- THSD1 | c.1801del p.E601Kfs*9 | Frame Shift Del (DEL) | VAF 85/424 reads (20%) | called by mutect2, pindel, varscan2
- TMEM132C | c.120G>T p.Q40H | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.034); called by muse, varscan2
- TRANK1 | c.3292G>T p.E1098* | Nonsense Mutation (SNP) | VAF 54/349 reads (15%) | called by muse, mutect2, varscan2
- TRO | c.2172C>A p.S724R | Missense Mutation (SNP) | VAF 57/344 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- TRPC4 | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- WDFY3 | c.9377A>G p.H3126R | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XYLT1 | c.2597C>A p.A866D | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.764); called by muse, varscan2
- ZCCHC2 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 31/273 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- ZFYVE26 | c.967G>T p.A323S | Missense Mutation (SNP) | VAF 132/658 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- ZNF99 | c.767C>A p.P256H | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZP4 | c.1219G>T p.D407Y | Missense Mutation (SNP) | VAF 55/501 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- AMER3 | c.1021C>A p.R341= | Silent (SNP) | VAF 33/160 reads (21%) | catalogued as COSV58466607; called by muse, mutect2, varscan2
- ANO4 | c.2805T>A p.R935= (on ENST00000392977 / NM_001286615.2; = p.R900= on NM_178826.4) | Silent (SNP) | VAF 73/392 reads (19%) | called by muse, mutect2, varscan2
- ATF7IP | c.3630C>A p.P1210= | Silent (SNP) | VAF 44/240 reads (18%) | catalogued as COSV53770507; called by muse, mutect2, varscan2
- CCDC40 | c.345G>T p.P115= | Silent (SNP) | VAF 84/426 reads (20%) | catalogued as COSV53896702; called by muse, mutect2, varscan2
- CD163L1 | c.4287C>T p.T1429= | Silent (SNP) | VAF 42/217 reads (19%) | catalogued as COSV58016634; called by muse, mutect2, varscan2
- CFAP61 | c.3345C>T p.R1115= | Silent (SNP) | VAF 148/766 reads (19%) | catalogued as rs1269283568, COSV55634012; called by muse, mutect2, varscan2
- CRX | c.9G>T p.A3= | Silent (SNP) | VAF 76/337 reads (23%) | called by muse, mutect2, varscan2
- DBH | c.1341C>A p.I447= | Silent (SNP) | VAF 169/410 reads (41%) | called by muse, mutect2, varscan2
- FRY | c.4614A>T p.T1538= | Silent (SNP) | VAF 85/435 reads (20%) | called by muse, mutect2, varscan2
- FZD4 | c.747C>T p.S249= | Silent (SNP) | VAF 72/590 reads (12%) | called by muse, mutect2, varscan2
- GIPR | c.240C>T p.A80= | Silent (SNP) | VAF 49/375 reads (13%) | called by muse, mutect2, varscan2
- GRHL1 | c.1599C>T p.L533= | Silent (SNP) | VAF 96/317 reads (30%) | called by muse, varscan2
- HEPACAM | c.342G>A p.L114= | Silent (SNP) | VAF 88/386 reads (23%) | called by muse, mutect2, varscan2
- IQCN | c.705G>T p.L235= | Silent (SNP) | VAF 23/87 reads (26%) | called by muse, mutect2, varscan2
- IQSEC2 | c.411C>T p.A137= | Silent (SNP) | VAF 36/150 reads (24%) | called by muse, mutect2, varscan2
- JAKMIP1 | c.1071C>T p.I357= | Silent (SNP) | VAF 60/278 reads (22%) | catalogued as COSV51548764, COSV99289587; called by muse, mutect2, varscan2
- KCNU1 | c.2803C>T p.L935= | Silent (SNP) | VAF 42/152 reads (28%) | called by muse, varscan2
- KCNU1 | c.2880G>T p.R960= | Silent (SNP) | VAF 45/162 reads (28%) | catalogued as rs769435361, COSV67757076; called by muse, varscan2
- KIF4B | c.2889G>T p.L963= | Silent (SNP) | VAF 146/658 reads (22%) | called by muse, mutect2, varscan2
- KRTAP4-5 | c.249C>A p.T83= | Silent (SNP) | VAF 36/228 reads (16%) | called by mutect2, varscan2
- LCE1F | c.324G>T p.G108= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs1301807899; called by muse, mutect2, varscan2
- ME2 | c.1188C>G p.G396= | Silent (SNP) | VAF 46/174 reads (26%) | called by muse, mutect2, varscan2
- MRPL3 | c.84G>T p.P28= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as rs931526885; called by muse, mutect2, varscan2
- NRBF2 | c.672G>A p.T224= | Silent (SNP) | VAF 56/276 reads (20%) | catalogued as rs549755878; called by muse, mutect2, varscan2
- OR6F1 | c.474G>T p.V158= | Silent (SNP) | VAF 41/353 reads (12%) | catalogued as COSV57467303; called by muse, mutect2, varscan2
- OR8B8 | c.726C>T p.S242= | Silent (SNP) | VAF 84/310 reads (27%) | called by muse, varscan2
- PSAPL1 | c.969C>T p.R323= | Silent (SNP) | VAF 64/324 reads (20%) | catalogued as rs370464084; called by muse, mutect2, varscan2
- RPUSD3 | c.210C>T p.L70= | Silent (SNP) | VAF 37/237 reads (16%) | called by muse, mutect2, varscan2
- SCML4 | c.618C>T p.P206= | Silent (SNP) | VAF 56/195 reads (29%) | called by muse, mutect2, varscan2
- SLC15A1 | c.207C>T p.L69= | Silent (SNP) | VAF 59/282 reads (21%) | catalogued as rs768700499, COSV64711886; called by muse, mutect2, varscan2
- SLC2A10 | c.9C>T p.H3= | Silent (SNP) | VAF 101/599 reads (17%) | catalogued as rs1423610543; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC37A2 | c.1215C>T p.Y405= | Silent (SNP) | VAF 45/232 reads (19%) | catalogued as rs745736571, COSV53522134; called by muse, mutect2
- SLC6A1 | c.669C>A p.I223= | Silent (SNP) | VAF 65/288 reads (23%) | called by muse, mutect2, varscan2
- SRC | c.493C>T p.L165= | Silent (SNP) | VAF 45/262 reads (17%) | called by muse, mutect2, varscan2
- SYT3 | c.1101G>A p.T367= | Silent (SNP) | VAF 44/162 reads (27%) | catalogued as rs766325612, COSV58898765; called by muse, mutect2, varscan2
- TAOK2 | c.1392C>T p.D464= | Silent (SNP) | VAF 11/120 reads (9%) | called by muse, mutect2
- TCF24 | c.243C>A p.P81= | Silent (SNP) | VAF 44/194 reads (23%) | called by muse, mutect2, varscan2
- TIAM1 | c.3846G>T p.L1282= | Silent (SNP) | VAF 90/427 reads (21%) | catalogued as COSV54538182; called by mutect2, varscan2
- TMEM144 | c.654T>C p.D218= | Silent (SNP) | VAF 39/348 reads (11%) | called by muse, mutect2, varscan2
- TNR | c.57G>C p.L19= | Silent (SNP) | VAF 147/448 reads (33%) | called by muse, mutect2, varscan2
- TRANK1 | c.3291G>A p.E1097= | Silent (SNP) | VAF 52/348 reads (15%) | called by muse, mutect2, varscan2
- ZNF536 | c.3033C>T p.S1011= | Silent (SNP) | VAF 36/247 reads (15%) | catalogued as rs781010251; called by muse, mutect2, varscan2
- A1CF | c.100-6612A>T | Intron (SNP) | VAF 48/259 reads (19%) | called by muse, mutect2, varscan2
- AC093791.1 | n.394C>T | RNA (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- AC140125.2 | n.481C>A | RNA (SNP) | VAF 44/278 reads (16%) | called by muse, varscan2
- ACSF3 | c.1614-2970G>T | Intron (SNP) | VAF 143/699 reads (20%) | called by muse, mutect2, varscan2
- ANKS1B | c.3672+5580G>T | Intron (SNP) | VAF 41/288 reads (14%) | catalogued as COSV59114703, COSV59121912; called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130915136 C>A | 5'Flank (SNP) | VAF 35/211 reads (17%) | called by muse, mutect2, varscan2
- ARL13B | c.*1269C>A | 3'UTR (SNP) | VAF 15/49 reads (31%) | called by muse, mutect2, varscan2
- B3GNTL1 | c.409-372T>G | Intron (SNP) | VAF 42/187 reads (22%) | catalogued as rs1217438716; called by muse, mutect2, varscan2
- CAMK2B | c.415-1434C>T | Intron (SNP) | VAF 42/212 reads (20%) | catalogued as rs1317750047; called by muse, mutect2, varscan2
- CFL2 | chr14:34714814 T>G | 5'Flank (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2, varscan2
- CSRP2 | c.281+224A>G | Intron (SNP) | VAF 24/82 reads (29%) | catalogued as rs1565821731; called by muse, mutect2, varscan2
- DCAF13 | chr8:103415266 T>C | 5'Flank (SNP) | VAF 58/325 reads (18%) | catalogued as rs760605028; called by muse, mutect2, varscan2
- DCHS2 | n.5522T>A | RNA (SNP) | VAF 79/356 reads (22%) | called by muse, mutect2, varscan2
- DHRS7 | c.-297+1000T>G | Intron (SNP) | VAF 48/261 reads (18%) | called by muse, mutect2, varscan2
- DST | c.4296+4432G>A | Intron (SNP) | VAF 91/637 reads (14%) | called by muse, mutect2, varscan2
- FBXO46 | c.*490G>A | 3'UTR (SNP) | VAF 12/102 reads (12%) | called by muse, mutect2, varscan2
- FOXRED1 | c.85+30G>T | Intron (SNP) | VAF 121/512 reads (24%) | called by muse, mutect2, varscan2
- GREM1 | c.-2+345C>T | Intron (SNP) | VAF 21/86 reads (24%) | catalogued as rs1474823204; called by muse, mutect2, varscan2
- IL16 | c.1903-1478T>A | Intron (SNP) | VAF 29/190 reads (15%) | called by muse, mutect2, varscan2
- NEK10 | c.568+58G>C | Intron (SNP) | VAF 54/205 reads (26%) | called by muse, mutect2, varscan2
- OACYLP | n.953C>A | RNA (SNP) | VAF 61/373 reads (16%) | called by muse, mutect2, varscan2
- PHIP | c.99+10C>T | Intron (SNP) | VAF 41/123 reads (33%) | called by muse, mutect2, varscan2
- SLC16A5 | c.-48-114C>T | Intron (SNP) | VAF 49/219 reads (22%) | called by muse, mutect2, varscan2
- SLC25A48 | c.679+91G>T | Intron (SNP) | VAF 5/24 reads (21%) | called by muse, varscan2
- SNORD116-17 | n.81G>C | RNA (SNP) | VAF 68/360 reads (19%) | called by muse, mutect2, varscan2
- SPEF2 | c.4448-3757C>A | Intron (SNP) | VAF 43/181 reads (24%) | called by muse, mutect2, varscan2
- SYT14 | c.*1275G>C | 3'UTR (SNP) | VAF 18/187 reads (10%) | called by muse, mutect2, varscan2
- TPRX2P | n.684G>T | RNA (SNP) | VAF 27/110 reads (25%) | called by muse, mutect2, varscan2
- TTN | c.10360+3571A>T | Intron (SNP) | VAF 83/229 reads (36%) | called by muse, mutect2, varscan2
- VPS29 | c.3+401G>T | Intron (SNP) | VAF 94/473 reads (20%) | catalogued as rs1055439975; called by muse, mutect2, varscan2
